Gene-level copy-number profile of tumor specimen REBC-ADKJ-TTP1-A from REBC case REBC-ADKJ, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: female; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ADKJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e179fc92-7b36-4fa9-bcf4-164e5c2e07ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ADKJ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/5a8dd14f-5076-4a44-b46d-72b2e76c16a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 20; copy number 2: 58,281; copy number 3: 11; copy number 4: 84.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:128,305,159–128,322,447, 2 genes: TRUB2, AL359091.3.
- chr19:186,373–246,544, 4 genes: SEPTIN14P19, CICP19, LINC01002, RNU6-1076P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
